Somatic mutation profile of tumor specimen MP2PRT-PATKHY-TMP1-A (aliquot MP2PRT-PATKHY-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATKHY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,040 days).
Specimen MP2PRT-PATKHY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf0d83d-6f84-4f19-859a-976a64ecc705.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKHY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKHY-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db66e060-e435-4118-9a51-6ee2a3998234

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MORC4 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs747662628, COSV55240017; called by muse, mutect2, varscan2
- OR10C1 | c.509G>A p.C170Y (on ENST00000622521; = p.C168Y on NM_013941.3) | Missense Mutation (SNP) | VAF 336/752 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762015707, COSV101010785; called by muse, mutect2, varscan2
- ZFYVE28 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 63/609 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs202215374; called by muse, mutect2, varscan2
- CENPI | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRBJ2-7 | chr7:142797453 GTGCTCC>TCCGGA | Missense Mutation (DEL) | VAF 169/489 reads (35%) | called by pindel, varscan2*
- RPE | c.141C>T p.I47= | Silent (SNP) | VAF 114/322 reads (35%) | catalogued as rs1044501997; called by muse, mutect2, varscan2
